Somatic mutation profile of tumor specimen 0DPQQM from CCDI case PBCDUV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 0.4 years (162 days).
Specimen 0DPQQM: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0430127c-a6dc-4ed5-8a12-acdc2ec015d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPQQB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca0fe836-3b63-4fb4-9448-74aa51e77dc8

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Frame Shift Ins 1, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.17347G>A p.D5783N | Missense Mutation (SNP) | VAF 167/408 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as rs562319458, COSV60914814; called by muse, mutect2, varscan2
- ZNF449 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 152/409 reads (37%) | catalogued as COSV100202996; called by muse, mutect2, varscan2
- DNAJB5 | c.328dup p.I110Nfs*16 | Frame Shift Ins (INS) | VAF 30/349 reads (9%) | called by mutect2, pindel
- AFM | c.1596C>T p.H532= | Silent (SNP) | VAF 52/325 reads (16%) | catalogued as rs768119669; called by muse, mutect2, varscan2
